Somatic mutation profile of tumor specimen TCGA-EM-A1YA-01A (aliquot TCGA-EM-A1YA-01A-11D-A14W-08) from TCGA case TCGA-EM-A1YA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 74.5 years (27,224 days).
Specimen TCGA-EM-A1YA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 862f8895-6a95-40b1-8bee-244ce496bafd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1YA-10A (Blood Derived Normal), aliquot TCGA-EM-A1YA-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7637d01-fc34-4f35-beed-11a12d5891ee

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.338-1G>T p.X113_splice | Splice Site (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); catalogued as COSV65450922, COSV65451214, COSV65451406; called by muse, mutect2, varscan2
- ALPK1 | c.3671A>G p.E1224G | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV51590741; called by muse, mutect2, varscan2
- EIF1AX | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV101096092; called by muse, mutect2, varscan2
- ENPP1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); catalogued as COSV62935595; called by muse, mutect2
- PSG9 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 115/290 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52487573; called by muse, mutect2, varscan2
- SPRED2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62694670; called by muse, mutect2
- SLC10A5 | c.648A>T p.P216= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as COSV72828467; called by muse, mutect2, varscan2
- FRMPD2B | n.714G>C | RNA (SNP) | VAF 55/236 reads (23%) | called by muse, mutect2, varscan2
- PKM | c.1141-560T>C | Intron (SNP) | VAF 3/50 reads (6%) | catalogued as COSV58791287; called by muse, mutect2
